Gene-level copy-number profile of tumor specimen ALCH-ADTR-TTP1-A from ALCHEMIST case ALCH-ADTR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 72.0 years (26,307 days).
Specimen ALCH-ADTR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 20816d84-a532-47e6-8327-5f0086e95874.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADTR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/2add0492-bb9a-4899-abd8-e3a9c0a90587

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 102; copy number 1: 7,619; copy number 2: 46,986; copy number 3: 3,754; copy number 4: 402; copy number 5: 20; copy number 6: 9; copy number 7: 1; copy number 8: 1; copy number 18: 2.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:43,991,500–44,031,467, 1 gene (within-gene range 0–2): SLC6A9.
- chr3:52,812,962–52,835,729, 4 genes (within-gene range 0–2): ITIH4, AC006254.1, ITIH4-AS1, MUSTN1.
- chr3:129,591,349–129,591,635, 1 gene (within-gene range 0–2): RN7SL752P.
- chr7:73,593,194–73,624,543, 2 genes: MLXIPL, AC005089.1.
- chr7:128,830,406–128,862,626, 2 genes (within-gene range 0–2): FLNC, FLNC-AS1.
- chr7:129,770,383–129,785,185, 4 genes: MIR182, MIR96, MIR183, AC084864.1.
- chr8:141,447,475–141,447,549, 1 gene (within-gene range 0–2): AC100803.1.
- chr9:121,574,891–121,576,214, 1 gene (within-gene range 0–2): AL357936.1.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–2): MIR601.
- chr9:124,481,236–124,507,420, 1 gene: NR5A1.
- chr10:38,403,189–38,452,153, 1 gene (within-gene range 0–2): AL133216.2.
- chr10:38,452,987–38,466,176, 2 genes: CICP9, AL133216.1.
- chr14:104,138,723–104,180,894, 1 gene: KIF26A.
- chr15:25,176,832–25,241,827, 36 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39.
- chr15:40,929,340–40,939,073, 1 gene: DLL4.
- chr16:75,218,988–75,268,053, 4 genes: CTRB1, AC009078.2, BCAR1, AC009078.3.
- chr17:80,453,735–80,477,843, 3 genes: AC120024.1, AC120024.4, NPTX1.
- chr22:18,533,646–18,611,919, 4 genes: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3.
- chr22:18,773,665–18,843,399, 3 genes: GGT3P, AC008132.2, E2F6P1.
- chr22:18,855,621–18,858,640, 1 gene (within-gene range 0–1): BCRP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 33 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:164,670,878–165,197,109, 6 genes, copy number 6: LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3.
- chr5:7,239,781–7,240,018, 1 gene, copy number 5: Metazoa_SRP.
- chr5:14,143,342–14,871,778, 12 genes, copy number 5: TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637.
- chr5:16,451,519–16,617,058, 2 genes, copy number 5: ZNF622, RETREG1.
- chr5:16,617,225–16,623,095, 2 genes, copy number 5: AC022113.1, Y_RNA.
- chr14:18,333,726–18,412,264, 2 genes, copy number 6–7: CR383658.1, CR383658.2.
- chr16:10,718,633–10,719,762, 1 gene, copy number 5: MTCYBP33.
- chr20:62,872,250–62,873,076, 1 gene, copy number 6: ARF4P2.
- chr22:18,615,581–18,757,906, 6 genes, copy number 5–18: Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E.

Autosomal genes at a single copy (total copy number 1): 4,826. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
